Surgical pathology report (de-identified scan), TCGA case TCGA-DW-5561, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DW-5561-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS:

1. Renal mass, left, #1 (resection): Papillary renal cell carcinoma, type I; incipient lesions are present
2. Renal mass, left #2 (resection): Papillary renal cell carcinoma, type I; incipient lesions are present.

NOTE:

CLINICAL INFORMATION: Allocate Order to Protocol: [REDACTED] 7 Brief Clinical History: Left renal mass Specimen Taken For Protocol: [REDACTED] - Yes

PROCEDURE: Pre-Operative Diagnosis: Left Renal Mass Post-Operative Diagnosis: Left Renal Mass Operative Findings: 3 cm left renal mass

SPECIMENS SUBMITTED: 1. KIDNEY, LEFT, Mass #1
2. KIDNEY, LEFT, Mass #2

GROSS DESCRIPTION: Received are 2 containers labeled with the patient's name, medical record number, and further described as follows:

1. "Tumor #1" is a single solid tan/yellow soft tissue fragment measuring 0.6 x 0.4 x 0.2 cm. Approximately 50% is procured for [REDACTED] Research and the remainder is preserved in formalin. The specimen is received in Surgical Pathology and is consistent with the above description. The specimen is wrapped in lens paper entirely submitted in a white cassette labeled [REDACTED] 1 for permanent processing.

Patient Identification

[page 2 of 2]
2. "Tumor #2" is a 4.2 x 4.0 x 4.0 soft tissue fragment. The specimen is inked in black and bisected to reveal a tumor with a relatively homogeneous white/yellow, fleshy cut surface. The tumor measures 3.5 x 3.6 x 3.6 cm. Approximately 1.5 x 1.0 x 0.4 cm of the tumor is procured for [REDACTED] Research and the remainder is preserved in formalin. The procurement was performed by [REDACTED] at [REDACTED]. The specimen is Surgical Pathology and is consistent with the above description. The remainder of the specimen is entirely submitted in white cassettes labeled [REDACTED] 8 2A-2P for permanent processing.

No consultants

Patient Identification

Source: NCI Genomic Data Commons file f7dbdcce-556c-4c3b-a72b-772f7c984a77 (TCGA-DW-5561.67DCF6D4-9AA6-45FA-AEF8-F45C6344DADE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).